Somatic mutation profile of tumor specimen C3N-01085-02 (aliquot CPT0212210006) from CPTAC case C3N-01085, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-01085-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8b3a40c-e37f-472f-be3f-a0dc8966d63f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01085-71 (Blood Derived Normal), aliquot CPT0212320002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4da078a-4824-4e49-9fb9-66b8b96574c7

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Frame Shift Del 5, Nonsense Mutation 3, RNA 2, 3'UTR 2, Frame Shift Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC185 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs1012767484, COSV64821931; called by muse, mutect2, varscan2
- CCNB3 | c.3319C>G p.P1107A | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV52079210; called by muse, mutect2
- DISP3 | c.681C>A p.S227R | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs769920986; called by muse, mutect2, varscan2
- GPHA2 | c.367A>G p.M123V | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs1429253874; called by muse, mutect2, varscan2
- LMNTD1 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV51450952; called by muse, mutect2
- N4BP3 | c.74C>A p.S25Y | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1037732606, COSV51067439; called by muse, mutect2
- PRPF4B | c.1141T>C p.S381P | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV61783865, COSV61784338; called by muse, mutect2, varscan2
- RALGAPB | c.2618C>G p.S873C | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53439350; called by muse, mutect2, varscan2
- TSC2 | c.337-2A>G p.X113_splice | Splice Site (SNP) | VAF 61/476 reads (13%) | catalogued as rs397515316; ClinVar: not provided; called by muse, mutect2, varscan2
- TSC2 | c.4290G>A p.W1430* | Nonsense Mutation (SNP) | VAF 44/536 reads (8%) | catalogued as rs45517334, CM091106; ClinVar: not provided; called by muse, mutect2
- XCL1 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363490248, COSV100892217; called by muse, mutect2
- AHNAK | c.10720G>T p.G3574W | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C15orf39 | c.1324C>A p.L442M | Missense Mutation (SNP) | VAF 51/457 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLN8 | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CSE1L | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.217); called by muse, mutect2
- DNAH3 | c.4844_4850del p.N1615Sfs*26 | Frame Shift Del (DEL) | VAF 58/554 reads (10%) | called by mutect2, pindel
- DNAJC25 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- DYNC1H1 | c.10670_10676del p.D3557Vfs*22 | Frame Shift Del (DEL) | VAF 74/644 reads (11%) | called by mutect2, pindel, varscan2
- ELAPOR2 | c.2910dup p.E971Rfs*3 (on ENST00000450689 / NM_001142749.3; = p.E804Rfs*3 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- IGLL5 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 58/692 reads (8%) | called by muse, mutect2
- MAPRE3 | c.395del p.G132Afs*4 | Frame Shift Del (DEL) | VAF 28/271 reads (10%) | called by mutect2, pindel, varscan2
- NOL10 | c.874_877del p.S292Efs*36 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- NUMA1 | c.4478A>G p.E1493G | Missense Mutation (SNP) | VAF 65/507 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PPP6R3 | c.1324G>T p.E442* (on ENST00000393800 / NM_001352375.2; = p.E391* on NM_018312.5) | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- PSMD11 | c.609_612del p.P204Nfs*47 | Frame Shift Del (DEL) | VAF 18/171 reads (11%) | called by mutect2, pindel, varscan2
- RHEX | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF103 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 68/452 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SETD1B | c.5523G>C p.L1841F | Missense Mutation (SNP) | VAF 61/540 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX19 | c.2860T>C p.C954R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SPSB3 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1565T>G p.L522R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF605 | c.1542T>A p.F514L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.2071T>C p.L691= | Silent (SNP) | VAF 41/370 reads (11%) | catalogued as rs1477637661; called by muse, mutect2, varscan2
- CXXC4 | c.864C>G p.S288= | Silent (SNP) | VAF 34/277 reads (12%) | catalogued as rs146939312; called by muse, mutect2, varscan2
- GRIA1 | c.315C>T p.H105= | Silent (SNP) | VAF 55/579 reads (9%) | catalogued as rs138090704; called by muse, mutect2, varscan2
- HDAC6 | c.717A>G p.Q239= | Silent (SNP) | VAF 39/347 reads (11%) | called by muse, mutect2, varscan2
- OR14A2 | c.474A>G p.T158= | Silent (SNP) | VAF 21/174 reads (12%) | called by muse, varscan2
- TTC6 | c.1473A>C p.A491= (on ENST00000267368; = p.A1857= on NM_001310135.3) | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- WASHC4 | c.1245A>G p.K415= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- ADAM21P1 | n.1888G>T | RNA (SNP) | VAF 30/265 reads (11%) | called by muse, mutect2, varscan2
- AGPAT3 | c.*2812A>G | 3'UTR (SNP) | VAF 59/470 reads (13%) | called by muse, mutect2, varscan2
- GUCY2D | c.3138+36C>A | Intron (SNP) | VAF 38/289 reads (13%) | called by muse, mutect2, varscan2
- OR5AK4P | n.299A>T | RNA (SNP) | VAF 6/59 reads (10%) | called by muse, varscan2
- VAPB | c.*4110T>A | 3'UTR (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
